Somatic mutation profile of tumor specimen 0DN636 from CCDI case PBCAYN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 16.4 years (5,991 days).
Specimen 0DN636: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c668ed74-dd44-4869-8a3d-59867e411eee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN62Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b51163a3-6ed8-4f4a-9391-623946e9526b

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, 3'UTR 3, 5'UTR 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 68/828 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2
- AK8 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 87/1474 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs775251005; called by muse, mutect2
- ANKRD30A | c.993G>T p.L331F (on ENST00000611781; = p.L275F on NM_052997.2) | Missense Mutation (SNP) | VAF 148/1646 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV64617046; called by muse, mutect2
- ATAD2 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 58/1349 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54878586; called by muse, mutect2
- ATRX | c.4756C>G p.P1586A | Missense Mutation (SNP) | VAF 26/914 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV64881845; called by muse, mutect2
- CUL4A | c.1292G>A p.R431Q (on ENST00000375440 / NM_001008895.4; = p.R331Q on NM_003589.3) | Missense Mutation (SNP) | VAF 64/1344 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs758802173; called by muse, mutect2
- FAM13B | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 91/1357 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338891683; called by muse, mutect2
- HNRNPM | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 44/704 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.166); catalogued as rs746414049, COSV55312225; called by muse, mutect2
- MINDY4 | c.2048G>C p.S683T | Missense Mutation (SNP) | VAF 40/728 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.244); catalogued as COSV99518658; called by muse, mutect2
- RNF17 | c.3548T>C p.F1183S | Missense Mutation (SNP) | VAF 94/1220 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99692585; called by muse, mutect2
- SDK2 | c.4733G>A p.R1578Q | Missense Mutation (SNP) | VAF 62/802 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs777693190, COSV101169023; called by muse, mutect2
- DCX | c.40_41insTATC p.T14Ifs*16 | Frame Shift Ins (INS) | VAF 66/574 reads (11%) | called by mutect2, varscan2
- LARS1 | c.528A>C p.E176D (on ENST00000394434 / NM_020117.11; = p.E149D on NM_016460.3) | Missense Mutation (SNP) | VAF 88/1362 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PPM1E | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 36/1020 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); called by muse, mutect2
- PTPN13 | c.5545G>A p.D1849N (on ENST00000411767 / NM_080683.3; = p.D1830N on NM_006264.3) | Missense Mutation (SNP) | VAF 62/1015 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2
- RP1 | c.1295C>A p.T432K | Missense Mutation (SNP) | VAF 127/1111 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TTN | c.98914G>A p.D32972N (on ENST00000591111; = p.D25548N on NM_003319.4) | Missense Mutation (SNP) | VAF 94/852 reads (11%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- FLRT3 | c.1131C>T p.A377= | Silent (SNP) | VAF 42/823 reads (5%) | called by muse, mutect2
- HR | c.720C>G p.A240= | Silent (SNP) | VAF 113/818 reads (14%) | catalogued as COSV100455828; called by muse, mutect2, varscan2
- IDE | c.2019C>T p.F673= | Silent (SNP) | VAF 70/986 reads (7%) | called by muse, mutect2
- OR2AT4 | c.324C>T p.L108= | Silent (SNP) | VAF 87/856 reads (10%) | called by muse, mutect2
- CACNG3 | c.-77G>A | 5'UTR (SNP) | VAF 8/84 reads (10%) | catalogued as rs1056338928; called by muse, mutect2
- CBLN2 | c.-52G>A | 5'UTR (SNP) | VAF 45/317 reads (14%) | called by muse, mutect2, varscan2
- LRCOL1 | c.*20G>A | 3'UTR (SNP) | VAF 45/695 reads (6%) | catalogued as rs989954057; called by muse, mutect2
- SZT2 | c.*3092A>G | 3'UTR (SNP) | VAF 55/437 reads (13%) | catalogued as rs755042181; called by muse, mutect2, varscan2
- TOR1B | c.*591T>C | 3'UTR (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- USH1C | c.1284+5454G>T | Intron (SNP) | VAF 74/1348 reads (5%) | catalogued as COSV50015096; called by muse, mutect2
